CCDI case PBBHVH — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Spinal cord, cranial nerves, and other parts of central nervous system.
https://portal.gdc.cancer.gov/cases/91516369-1b1a-4b2f-866c-cffd10a3f42f

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Spinal cord; Age at diagnosis: 13.1 years (4,768 days).

Biospecimens (3 samples)
- Sample 0D8ODU: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0D8ODV: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0D8ODW: Tissue type: Tumor; Specimen type: Solid Tissue.
